Gene-level copy-number profile of tumor specimen TCGA-EB-A5VU-01A from TCGA case TCGA-EB-A5VU, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 56.4 years (20,618 days).
Specimen TCGA-EB-A5VU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.8b4c9e78-4832-4f94-9c4b-3039d695c2b9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EB-A5VU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5e7ab33d-67cc-46e7-8173-922753b3555c

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 200; copy number 2: 12,338; copy number 3: 15,379; copy number 4: 26,776; copy number 5: 4,043; copy number 6: 112; copy number 7: 288; copy number 8: 69; copy number 9: 169; copy number 15: 113; copy number 16: 7; copy number 19: 139; copy number 20: 1; copy number 23: 42; copy number 26: 134.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EB-A5VU-01A-21D-A32M-01): tumor purity 0.64, ploidy 3.41, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:181,064,089–181,700,142, 6 genes: LINC00290, AC019235.1, LINC02500, AC093840.1, AC093840.2, AC084741.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 605 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:91,023,919–92,486,925, 25 genes, copy number 9: RPL5P6, HFM1, Y_RNA, FEN1P1, CDC7, WDR82P2, AL714022.1, HSP90B3P, TGFBR3, RN7SL653P, BRDT, EPHX4, LPCAT2BP, SETSIP, BTBD8, GAPDHP46, PRKAR1AP1, AC104836.1, AL663109.1, C1orf146, ACTBP12, GLMN, RPAP2, RN7SL824P, GFI1.
- chr1:111,007,700–116,571,039, 144 genes, copy number 9 (broad region; genes not listed).
- chr17:20,008,051–21,783,465, 90 genes, copy number 15 (broad region; genes not listed).
- chr20:45,857,614–54,269,542, 187 genes, copy number 19–26 (within-gene range 2–26) (broad region; genes not listed).
- chr20:57,105,741–57,163,775, 4 genes, copy number 15: AL157414.2, AL157414.1, AL157414.4, AL157414.3.
- chr20:58,981,208–59,259,113, 7 genes, copy number 16 (within-gene range 4–16): NELFCD, CTSZ, TUBB1, ATP5F1E, PRELID3B, MRPS16P2, ZNF831.
- chr20:59,624,904–59,628,295, 1 gene, copy number 20: PHACTR3-AS1.
- chr20:60,755,001–60,767,279, 1 gene, copy number 15 (within-gene range 4–15): AL117372.1.
- chr20:61,077,224–64,313,132, 146 genes, copy number 15–19 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 200. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
